Surgical pathology report (de-identified scan), TCGA case TCGA-BR-A452, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-A452-01A (Primary Tumor).

Procurement Date: Laterality: Mucosa is ulcerated. Tumor is invasion into serosa and lymph node. Tumor is composed of adenoid groups. Some tubules are dilated to form cyst containing necrosis. Glands are variability in size and shape. Tumor cells are moderately stratified. Mitotic index is present. Nuclei are hyperchromatic and irregularly enlarged and prominent nucleoli. Stroma is invasion of inflammatory cells

Path Report: STOMACH TISSUE CHECKLIST

Specimen type: Gastrectomy

Tumor site: Antrum

Tumor size: 8 x 7 x 5 cm

Tumor features: Ulcerated

Histologic type: Tubular adenocarcinoma ✓

Histologic grade: Poorly differentiated

Tumor extent: Serosa (visceral peritoneum)

Lymph nodes: 2/4 positive for metastasis (Regional lymph node, group vii 0/1, Regional lymph node, group i 0/1, Regional lymph node, group viii 2/2)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Perineural invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-O-3
adenocarcinoma, tubular
8211/3
Site: Stomach, antrum
8-31-12
RD
C16.3

Source: NCI Genomic Data Commons file 124e1cf7-89e0-40cf-bf47-d05da2d781d6 (TCGA-BR-A452.CAD6E7A0-0E24-4868-B869-878020622282.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).